Gene-level copy-number profile of tumor specimen TCGA-24-1431-01A from TCGA case TCGA-24-1431, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.8 years (24,758 days).
Specimen TCGA-24-1431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.bf3ced77-b793-484a-8bfa-7ffabbf491cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1431-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/be4cc6ae-a3f0-4e12-b084-3402b4e96152

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6,000; copy number 2: 18,537; copy number 3: 21,134; copy number 4: 13,367; copy number 5: 369; copy number 6: 84; copy number 7: 199; copy number 8: 104; copy number 9: 9; copy number 10: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1431-01A-01D-0472-01): tumor purity 0.9, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 323 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:18,704,433–19,234,487, 9 genes, copy number 9: LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15.
- chr5:92,082,597–92,939,591, 8 genes, copy number 7 (within-gene range 3–7): AC114316.1, AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058.
- chr11:65,422,774–65,595,996, 22 genes, copy number 8 (within-gene range 4–8): NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1, KCNK7.
- chr11:121,101,243–121,453,013, 7 genes, copy number 8 (within-gene range 4–8): TECTA, AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1.
- chr17:28,018,770–29,930,276, 125 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr17:39,603,536–39,747,291, 11 genes, copy number 10: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr19:14,826,241–16,103,002, 75 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr19:16,479,067–16,628,204, 1 gene, copy number 7 (within-gene range 3–7): AC008764.1.
- chr19:16,549,831–17,583,162, 65 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,579. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
